Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A3R7, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A3R7-01A (Primary Tumor).

[page 1 of 3]
Report for

TEST: Surgical Pathology
Collected Date & Time:

Result Name	Results	Units	Reference Range
Surgical Pathology	SURGICAL P		
SURGICAL PATHOLOGY REPORT			

Patient Name:
Accession #
Med. Rec. #:
Billing Type: Outpatient
Location:
DOB: (Age:
Service: Surgery
Gender:
Billing:
Taken Received Reported:
Physician(s):

Reviewed Initials	3/2/12	

Specimen(s) Received

- A: Right thyroid lobe
- B: Left thyroid lobe
- C: Right paratracheal nodes, level 6

Pathologic Diagnosis

- A. Right thyroid, lobectomy:
- Papillary thyroid carcinoma, right lobe.
- Size: 2.0 cm.
- Classical variant.
- Tumor focally extends to involve perithyroidal adipose tissue.
- Papillary thyroid carcinoma focally approaches to within <1 mm of the cauterized soft tissue margin.
- No lymph-vascular invasion identified.
- B. Left thyroid, lobectomy:
- Papillary thyroid carcinoma, left lobe, single focus.
- Size: 3 mm.
- Classical variant.
- No extrathyroidal extension identified.
- Resection margins negative.
- C. Right paratracheal lymph nodes, level 6:
- 2-of-2 lymph nodes positive for metastatic papillary thyroid carcinoma.
- Single benign parathyroid gland identified.

CAP CANCER CHECKLIST: THYROID GLAND RESECTION

Procedure: Thyroid lobectomy, right and left

Specimen Integrity: Intact

Specimen Size:

Right lobe: 4.5 x 2.4 x 1.5 cm

Left lobe: 4 x 2 x 1.4 cm

Specimen Weight: 11 g aggregate

Tumor Focality: Multifocal bilateral

Dominant Tumor:

Tumor Laterality: Right lobe

ICD-03

carcinoma, papillary, thyroid
8260/3

Site: thyroid C73.9

3-30-12

[page 2 of 3]
Tumor Size: 2.0 cm
Histologic Type: Papillary carcinoma
Variant: Classical
Architecture: Classical
Cyтомorphology: Classical
Margins:
Distance of invasive
Carcinoma to closest
Margin: <1 mm
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present
Lymph-Vascular Invasion: Not identified
Extrathyroidal Extension: Present, minimal
Second Tumor:
Tumor Laterality: Left lobe
Tumor Size: 0.4 cm
Histologic Type: Papillary carcinoma
Variant: Classical
Architecture: Classical
Cyтомorphology: Classical
Margins: Uninvolved
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Extrathyroidal Extension: Not identified

PATHOLOGIC STAGE: pT3, pN1a, pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated and does not incorporate other relevant data. Pathology stage is only a component to be considered in determining the clinical stage and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

Additional Pathologic Findings: Thyroiditis,
focal

Primary Pathologist: [REDACTED]

Electronically Signed Out by: [REDACTED]
[REDACTED]

Clinical History

Papillary thyroid cancer.

Gross Description

A. Received fresh labeled "right lobe of thyroid" is a thyroid lobe weighing 7 g and measuring 4.5 x 2.4 x 1.5 cm. The specimen is oriented by two stitches, designated by the requisition form as "single stitch isthmus, double stitch superior pole." The entire thyroid lobe is inked blue, and the isthmus is inked orange (the isthmus is 0.9 x 0.5 x 0.3 cm). Sectioning demonstrates an ill-defined mass with firm, gray areas and soft, pink areas, measuring 2.0 cm in greatest dimension. The mass abuts the inked surface of the thyroid. The mass is located in the inferior portion adjacent to the isthmus. There are no additional lesions or suspicious areas identified. The remainder of the specimen consists of dark red normal thyroid parenchyma. The specimen is entirely submitted from inferior to superior in

[page 3 of 3]
cassettes A1 through A8.

B. Received in formalin labeled "left thyroid lobe" is a thyroid lobe weighing 4 g and measuring 4.0 x 2.0 x 1.4 cm, with a portion of isthmus measuring 0.7 x 0.6 x 0.2 cm. The specimen is oriented by two sutures, designated by the requisition form and container label as "single stitch isthmus, double stitch superior pole."

The thyroid lobe is inked black and the isthmus is inked yellow. Sectioning demonstrates mostly unremarkable red parenchyma with a few foci of ill-defined firm, gray-white tissue in the midportion to inferior third of the specimen, measuring up to 0.6 cm in greatest dimension.

The specimen is entirely submitted from superior to inferior in cassettes B1 through B5. The ill-defined gray-white tissue is in cassettes B3 and B4.

C. Received in formalin labeled "right paratracheal nodes level 6" is a portion of fibroadipose tissue containing lymph nodes measuring 4 x 2 x 0.7 cm in aggregate. The specimen is dissected for lymph nodes, and there are three lymph nodes identified ranging from 0.6 to 1.1 cm in greatest dimension.

Cassette summary: C1 two lymph nodes, bisected (one uninked, one inked blue); C2 one lymph node, bisected; C3 and C4 remaining fibroadipose tissue, entirely submitted.

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

Interpretation performed at [REDACTED]

Source: NCI Genomic Data Commons file 5f2cd942-617a-4e04-949c-a53d37c81c06 (TCGA-FY-A3R7.1D97E5A9-0629-4545-9BCE-2E7729C031A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).